Somatic mutation profile of tumor specimen TCGA-44-6775-01A (aliquot TCGA-44-6775-01A-11D-1855-08) from TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-44-6775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d4a338a-70c1-4f6a-afaf-c0ccc7493315.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6775-10A (Blood Derived Normal), aliquot TCGA-44-6775-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08072e4f-0861-4fc6-90d2-21624660541f

The open-access MAF lists 64 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- ADAMTS12 | c.4370G>A p.W1457* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as rs776770546, COSV61276279, COSV61280573; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- ARHGAP21 | c.2883G>T p.M961I | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57611270; called by muse, mutect2
- ARHGEF10L | c.2272+2T>G p.X758_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV51440804; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as COSV63439114; called by muse, mutect2
- CDH18 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56936695, COSV56962343; called by muse, mutect2, varscan2
- CDH9 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV50346367; called by muse, mutect2
- CSMD3 | c.7704C>A p.Y2568* (on ENST00000297405 / NM_001363185.1; = p.Y2464* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV52134658, COSV52266109; called by muse, varscan2
- CTC1 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV59852041; called by muse, mutect2, varscan2
- CWC27 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759472038, COSV66888888; called by muse, mutect2, varscan2
- CXCR2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59282156; called by muse, mutect2, varscan2
- DPP10 | c.1222-1G>A p.X408_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | catalogued as COSV59684633, COSV59730084; called by muse, mutect2
- FBXW9 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100790258; called by muse, mutect2, varscan2
- FDPS | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV52742913; called by muse, mutect2, varscan2
- GABRA2 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 88/418 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV62920160; called by muse, mutect2, varscan2
- GABRA4 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51929438; called by muse, mutect2, varscan2
- GLYATL1 | c.563G>A p.R188Q (on ENST00000317391 / NM_001354699.1; = p.R219Q on NM_080661.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs746647261, COSV55607200; called by muse, mutect2, varscan2
- HRNR | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV64263127; called by muse, mutect2
- IBSP | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1262583902, COSV56897395; called by muse, mutect2, varscan2
- ITGAV | c.2124G>T p.Q708H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.677); catalogued as COSV53719113; called by muse, mutect2
- KAT2B | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55434770; called by muse, mutect2, varscan2
- KATNAL1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV66064908; called by muse, mutect2, varscan2
- KLF17 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64857036; called by muse, mutect2, varscan2
- KLHL4 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64143984, COSV64148115; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV59113372; called by muse, mutect2, varscan2
- MIB2 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61757586; called by muse, mutect2
- MRPS5 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV55535461; called by muse, mutect2, varscan2
- MVP | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420867632, COSV62423622; called by muse, mutect2
- MYT1 | c.2528+2T>C p.X843_splice | Splice Site (SNP) | VAF 132/307 reads (43%) | catalogued as COSV60513900; called by muse, mutect2, varscan2
- NBPF10 | c.11364G>T p.Q3788H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs587642846, COSV61673644; called by mutect2, varscan2
- NCF2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV61634370; called by muse, mutect2
- NF1 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as CD1415163, COSV62222291; called by muse, mutect2, varscan2
- PSEN1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56197081; called by muse, mutect2
- PTPRN | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1181242319, COSV55352439; called by muse, mutect2, varscan2
- RB1 | c.1846_1847insT p.K616Ifs*37 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | catalogued as COSV99922623; called by mutect2, pindel, varscan2
- REG3A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs1048512257, COSV59408975, COSV59410712, COSV59411752; called by muse, mutect2, varscan2
- SAGE1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV61018235; called by muse, mutect2, varscan2
- SBF2 | c.4099A>G p.T1367A | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1362020336, COSV56311943; called by muse, mutect2, varscan2
- SLC22A6 | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV64561072, COSV64561144; called by muse, mutect2
- TEC | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs746395396, COSV63354027; called by muse, mutect2, varscan2
- TNC | c.6098G>T p.R2033L | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60790736; called by muse, mutect2, varscan2
- TTN | c.16311G>C p.K5437N (on ENST00000591111; = p.K4510N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen possibly damaging (0.663); catalogued as COSV60358967; called by muse, mutect2, varscan2
- UGGT2 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65079669; called by muse, mutect2, varscan2
- VPS13C | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV51425770; called by muse, mutect2, varscan2
- VWA3B | c.3311T>C p.V1104A | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs927356360, COSV69034257; called by muse, mutect2, varscan2
- YTHDC1 | c.1867T>A p.Y623N (on ENST00000344157 / NM_001031732.4; = p.Y605N on NM_133370.4) | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60012155; called by muse, mutect2, varscan2
- ZBTB7B | c.746G>A p.G249E (on ENST00000292176; = p.G283E on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV52694899; called by muse, mutect2, varscan2
- BCL9L | c.3185dup p.S1062Rfs*108 | Frame Shift Ins (INS) | VAF 21/112 reads (19%) | called by mutect2, pindel, varscan2
- MET | c.3020_3028+4delinsG p.X1007_splice | Splice Site (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2*
- AUP1 | c.693C>T p.R231= | Silent (SNP) | VAF 48/181 reads (27%) | catalogued as COSV51214379; called by muse, mutect2, varscan2
- FBXO4 | c.693C>T p.F231= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV55854301; called by muse, mutect2, varscan2
- ICAM1 | c.1359C>G p.G453= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs750997842, COSV53427302; called by muse, mutect2, varscan2
- KCNA4 | c.1350A>G p.R450= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV60256061; called by muse, mutect2, varscan2
- KRTAP3-2 | c.141C>T p.C47= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV101195993; called by muse, mutect2
- PCDHGA9 | c.351C>T p.Y117= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs1561687273, COSV53967367; called by muse, mutect2, varscan2
- RBM15 | c.720C>T p.L240= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV63924504; called by muse, mutect2, varscan2
- RFC1 | c.3180A>G p.A1060= (on ENST00000381897 / NM_001363496.2; = p.A1059= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as COSV56470330; called by muse, mutect2, varscan2
- TAF2 | c.501G>A p.E167= | Silent (SNP) | VAF 13/301 reads (4%) | catalogued as COSV65421267; called by muse, mutect2
- TBL2 | c.837C>A p.S279= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV59788399; called by muse, mutect2
- TTLL3 | c.1179C>A p.L393= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100047064, COSV59615907; called by muse, mutect2, varscan2
- VBP1 | c.375G>A p.L125= | Silent (SNP) | VAF 45/222 reads (20%) | catalogued as COSV99660659; called by muse, mutect2, varscan2
- ZMYM5 | c.1023T>C p.C341= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as COSV61990061; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501251 del AT | 5'Flank (DEL) | VAF 12/70 reads (17%) | catalogued as rs751290649; called by pindel, varscan2
